Somatic mutation profile of tumor specimen TCGA-DC-6157-01A (aliquot TCGA-DC-6157-01A-11D-1657-10) from TCGA case TCGA-DC-6157, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 48.8 years (17,807 days).
Specimen TCGA-DC-6157-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32a46182-235e-4a4a-a7d0-f0dca0caed50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-6157-10A (Blood Derived Normal), aliquot TCGA-DC-6157-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a271a67-a8b2-47ef-9ab5-836f99022c83

The open-access MAF lists 94 somatic variants for this specimen: 74 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 17, Nonsense Mutation 7, Splice Site 3, In Frame Del 2, Frame Shift Ins 1, RNA 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 48/106 reads (45%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 32/111 reads (29%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 20/32 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-1G>C p.X33_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2
- ABCA8 | c.452A>T p.H151L | Missense Mutation (SNP) | VAF 103/263 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV52195579; called by muse, mutect2, varscan2
- ARHGAP21 | c.5509C>T p.R1837W | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs151326840; called by muse, mutect2, varscan2
- ARSJ | c.1418G>A p.S473N | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV100192598; called by muse, mutect2
- C5 | c.668-1G>T p.X223_splice | Splice Site (SNP) | VAF 56/563 reads (10%) | catalogued as COSV56324417; called by muse, mutect2, varscan2
- CBLB | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 73/481 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99913204; called by muse, mutect2, varscan2
- CEP89 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 118/940 reads (13%) | catalogued as COSV59862230; called by muse, mutect2, varscan2
- CYP2A7 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs373592664; called by muse, mutect2, varscan2
- DCC | c.2261T>C p.V754A | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV59087304; called by muse, mutect2, varscan2
- DNAH11 | c.2813T>G p.L938W | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV100178629; called by muse, mutect2, varscan2
- ELMO1 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 52/559 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs868556780, COSV60296747; called by muse, mutect2
- EPHB1 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs749600936, COSV67655033; called by muse, mutect2, varscan2
- EVPL | c.4690A>G p.I1564V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100044343; called by muse, mutect2
- FAM135B | c.3346T>G p.L1116V | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.918); catalogued as COSV52708161; called by muse, mutect2
- FER | c.278A>T p.N93I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.373); catalogued as COSV99812382; called by muse, mutect2, varscan2
- FER1L5 | c.4181A>C p.Y1394S (on ENST00000623019; = p.Y1367S on NM_001293083.2) | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV67605762; called by muse, mutect2, varscan2
- GLDC | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs763517274, CM1510182, COSV58676888; called by muse, mutect2
- GNAZ | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs766030793, COSV50737047; called by muse, mutect2, varscan2
- GOLGA4 | c.5509G>A p.D1837N | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs148910546; called by muse, mutect2, varscan2
- GRM1 | c.2131T>C p.S711P | Missense Mutation (SNP) | VAF 80/232 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); catalogued as COSV51110791; called by muse, mutect2, varscan2
- GRM7 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs952338137, COSV63143156; called by muse, mutect2
- GUCY1A1 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.567); catalogued as COSV56649561; called by muse, mutect2, varscan2
- HLA-B | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.262); catalogued as COSV69520663, COSV69521156; called by muse, mutect2, varscan2
- HOXA7 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as COSV54216805; called by muse, mutect2, varscan2
- KIAA0319 | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65496670; called by muse, mutect2, varscan2
- KLHL30 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375543545, COSV59974424; called by muse, mutect2, varscan2
- KMT5B | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs188627113, COSV58564134; called by muse, mutect2, varscan2
- KRT85 | c.1202G>T p.C401F | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.114); catalogued as COSV57736094; called by muse, mutect2, varscan2
- LRRC8E | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs753534988, COSV100142823; called by muse, mutect2, varscan2
- LSR | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs868581593, COSV61554714; called by muse, mutect2, varscan2
- MAK | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs747349238, COSV100504363; called by muse, mutect2, varscan2
- MYH7B | c.497A>T p.N166I | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53417042; called by muse, mutect2, varscan2
- MYLK4 | c.75dup p.Q26Sfs*27 | Frame Shift Ins (INS) | VAF 93/346 reads (27%) | catalogued as rs762913642; called by mutect2, pindel, varscan2
- NBAS | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs781766556, COSV55724746; called by muse, mutect2, varscan2
- NMNAT3 | c.377-1G>T p.X126_splice (on ENST00000296202 / NM_001320512.1; = p.X89_splice on NM_178177.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 7/53 reads (13%) | catalogued as COSV56155116; called by muse, mutect2, varscan2
- NOL11 | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 151/306 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs547266367, COSV53522345; called by muse, mutect2, varscan2
- OR51L1 | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 119/601 reads (20%) | catalogued as rs199934313, COSV58624036; called by muse, mutect2, varscan2
- PABPC3 | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as rs749042088, COSV55798033; called by muse, mutect2, varscan2
- PCDHA9 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554144146, COSV65323796; called by muse, mutect2, varscan2
- PDE4D | c.2114G>A p.R705H (on ENST00000340635 / NM_001104631.2; = p.R569H on NM_006203.4) | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV57715297; called by muse, mutect2, varscan2
- PER2 | c.1192A>G p.I398V | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs755886185, COSV54521696; called by muse, mutect2, varscan2
- PHRF1 | c.4097C>T p.A1366V (on ENST00000264555 / NM_001286581.2; = p.A1365V on NM_020901.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs201571276; called by muse, mutect2, varscan2
- PHTF2 | c.2250G>T p.M750I (on ENST00000248550 / NM_001366089.1; = p.M712I on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/666 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV50323884; called by muse, mutect2
- POLA2 | c.1438C>A p.L480M | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as COSV99640803; called by muse, mutect2, varscan2
- POLQ | c.1606C>G p.L536V | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs758335813, COSV99952054; called by muse, mutect2, varscan2
- PTPRF | c.5005C>T p.R1669W | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63444807; called by muse, mutect2
- PUM1 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs143359453; called by muse, mutect2, varscan2
- RALGPS2 | c.62G>C p.S21T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV61335836; called by muse, mutect2, varscan2
- RB1CC1 | c.12T>A p.Y4* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99211601; called by muse, mutect2, varscan2
- RBM27 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.964); catalogued as rs750452481, COSV54587811; called by muse, mutect2, varscan2
- RGS3 | c.544G>C p.D182H (on ENST00000350696 / NM_001282923.2; = p.D70H on NM_017790.4) | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.711); catalogued as COSV58277627; called by muse, mutect2, varscan2
- RREB1 | c.2969A>T p.E990V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV58554176; called by muse, mutect2, varscan2
- SAMM50 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as rs143794573; called by muse, mutect2, varscan2
- SEC14L3 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354696699, COSV53178203; called by muse, mutect2, varscan2
- SHANK1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53244156; called by muse, mutect2, varscan2
- SLC35G2 | c.205T>C p.F69L | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1176722595, COSV67587881; called by muse, mutect2
- SLC35G2 | c.207T>A p.F69L | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV67587887; called by muse, mutect2
- SNAP25 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV54770765, COSV54770930; called by muse, mutect2, varscan2
- SNTN | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV59538633, COSV59539478; called by muse, mutect2, varscan2
- SPRR2A | c.69C>A p.C23* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV101198734; called by muse, mutect2
- TINAGL1 | c.172C>G p.R58G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54699334; called by mutect2, varscan2
- TP53TG5 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs1471547349, COSV65577373; called by muse, mutect2, varscan2
- TSPO | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs141002863; called by muse, varscan2
- TTN | c.51913G>C p.V17305L (on ENST00000591111; = p.V9881L on NM_003319.4) | Missense Mutation (SNP) | VAF 9/123 reads (7%) | PolyPhen possibly damaging (0.826); catalogued as COSV59910175; called by muse, mutect2
- TXLNB | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 144/460 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV64443240; called by muse, varscan2
- UNC5D | c.788C>G p.A263G | Missense Mutation (SNP) | VAF 163/263 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV54773111, COSV54841837; called by muse, mutect2, varscan2
- XIRP2 | c.1806G>T p.Q602H (on ENST00000628543; = p.Q777H on NM_152381.6) | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54685284; called by muse, mutect2, varscan2
- ADGRB2 | c.1665_1667del p.N555del | In Frame Del (DEL) | VAF 30/50 reads (60%) | called by pindel, varscan2
- DCP2 | c.1119_1121del p.S376del | In Frame Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel, varscan2
- KRTAP10-12 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by mutect2, varscan2
- TUBGCP5 | c.2257C>A p.Q753K | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- AOC1 | c.1023C>T p.F341= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs553084982, COSV62867172; called by muse, mutect2, varscan2
- ARL13B | c.624G>A p.Q208= (on ENST00000394222 / NM_001174150.2; = p.Q101= on NM_144996.4) | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as COSV57396501; called by muse, mutect2, varscan2
- CEP162 | c.600G>A p.E200= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV57617821; called by muse, mutect2, varscan2
- CHKA | c.609C>T p.G203= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV55838668; called by muse, mutect2
- FAP | c.1368C>T p.S456= | Silent (SNP) | VAF 51/244 reads (21%) | catalogued as rs199889478, COSV51859649; called by muse, mutect2, varscan2
- FSD1 | c.936G>A p.A312= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs144756712, COSV55694846; called by muse, mutect2, varscan2
- FXR1 | c.885A>G p.K295= | Silent (SNP) | VAF 246/450 reads (55%) | catalogued as COSV59761290, COSV99976169; called by muse, mutect2, varscan2
- GSS | c.597C>T p.Y199= | Silent (SNP) | VAF 39/246 reads (16%) | catalogued as rs749301244, COSV53812191; called by muse, mutect2, varscan2
- ITIH2 | c.1638G>A p.T546= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs150260189, COSV64432132; called by muse, mutect2
- KLF12 | c.417G>A p.S139= | Silent (SNP) | VAF 30/171 reads (18%) | catalogued as rs748128269, COSV66570176; called by muse, mutect2, varscan2
- LAMA5 | c.3642C>A p.G1214= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV99439319; called by muse, mutect2
- NEXN | c.753T>C p.F251= | Silent (SNP) | VAF 34/192 reads (18%) | catalogued as COSV99630310; called by muse, varscan2
- PRKD1 | c.1017G>C p.V339= | Silent (SNP) | VAF 18/212 reads (8%) | catalogued as COSV59560535; called by muse, mutect2
- RFPL1 | c.387G>A p.L129= | Silent (SNP) | VAF 31/264 reads (12%) | catalogued as COSV62977443; called by muse, mutect2, varscan2
- RYR3 | c.12378G>A p.A4126= (on ENST00000389232; = p.A4127= on NM_001036.6) | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs374756167; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPNS2 | c.1497G>A p.L499= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV54594312; called by muse, mutect2, varscan2
- ZNF780B | c.153G>A p.K51= | Silent (SNP) | VAF 49/291 reads (17%) | catalogued as COSV55462098; called by muse, mutect2, varscan2
- PI4KA | chr22:20859122 C>T | 5'Flank (SNP) | VAF 25/86 reads (29%) | catalogued as COSV53142106; called by muse, mutect2
- RPS6KA4 | c.1335-26G>A | Intron (SNP) | VAF 23/44 reads (52%) | catalogued as rs981102202, COSV99589937; called by muse, mutect2, varscan2
- SSPOP | n.13991C>G | RNA (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100947265; called by mutect2, varscan2
